Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88R, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88R-01A (Primary Tumor).

[page 1 of 5]
Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
Surgical Pathology CASE NUMBER: DIAGNOSIS:	Final

1. Lymph nodes, anterior fat, resection: Fatty tissue and nerve.
2. Lymph nodes, obturator, resection: Segment of vessel.
3. Lymph nodes, obturator, left, resection: Lymph nodes (0/11). No tumor seen.
4. Lymph nodes, external iliac, right, resection: Lymph nodes (0/9). No tumor seen.
5. Lymph nodes, external iliac left, resection: Lymph nodes (0/3). No tumor seen.
6. Lymph nodes, common iliac, right, resection: Lymph nodes (0/6). No tumor seen.
7. Lymph node, common iliac, left, resection: Lymph nodes (0/2). No tumor seen.
8. Lymph node, internal iliac, right, resection: Lymph nodes (0/1). No tumor seen.
9. Lymph node, internal iliac, left, resection: Lymph nodes (0/2). No tumor seen.
10. Prostate, prostatectomy: Adenocarcinoma, Gleason score 8 (4+4) involving 30% of the left and 10% of the right lobes. Perineural invasion present. Areas suspicious for vascular invasion identified. No seminal vesicle involvement seen. Margins of resection are free from tumor. See Note.

NOTE: Extracapsular invasion cannot be properly evaluated due to tissue procurement.

CAP Cancer Protocol

Procedure : Radical prostatectomy

Prostate Size:

Weight: 61.30 g

Size: 5.0 x 4.3 x 4.2 cm

Lymph Node Sampling: Pelvic lymph node dissection

Histologic Type: Adenocarcinoma (acinar, not otherwise specified)

Histologic Grade; Gleason Pattern:

Primary Pattern: Grade 4

Secondary Pattern: Grade 4

Total Gleason Score: 8

Tumor Quantitation Proportion (percentage) of prostate involved by tumor: 40%

ICD-O-3
Adenocarcinoma, acinar
8140/3
Site: Prostate NOS
C61.9
9/11/13

[page 2 of 5]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age: :
			Location:

Surgical Pathology	Final Results
---------------------------	----------------------

Extraprostatic Extension: Cannot be assessed.
Seminal Vesicle Invasion (Invasion of muscular wall required): Not identified

Margins: Margins uninvolved by invasive carcinoma

Treatment Effect on Carcinoma: Not identified

Lymph-Vascular Invasion: Suspicious

Perineural Invasion: Present, extensive

Pathologic Staging (pTNM):

Primary Tumor (pT):

pT2c: Bilateral disease

Regional Lymph Nodes (pN):

pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined: 34

Number of Lymph Nodes Involved: 0

Distant Metastasis (pM):

Not applicable

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: with prostate cancer

Specimen Taken For

Protocol: Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: see dictation Post-Operative

Diagnosis: prostate

cancer Pre-Operative Diagnosis: prostate cancer

SPECIMENS SUBMITTED: 1. ROUTINE + 3FR.SLIDES, Left mid (1FS)

2. LYMPH NODES, Fat anterior to prostate

3. OBTURATOR LYMPH NODE(S), Right

4. OBTURATOR LYMPH NODE(S), Left

5. LYMPH NODES, Right external iliac

6. LYMPH NODES, Left external iliac

7. LYMPH NODES, Right common iliac

8. LYMPH NODES, Left common iliac

9. LYMPH NODES, Right internal iliac

10. LYMPH NODES, Left internal iliac

11. PROSTATE

INTRAOPERATIVE CONSULTATION:

[page 3 of 5]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology	Final Results
---------------------------	----------------------

"Left mid prostate margin"

1FS diagnosis: Fibrous tissue and nerve. No tumor seen.

GROSS DESCRIPTION: Received fresh from the OR labeled with the patient's name _____ the patient's medical record number _____ patient's date of birth _____ further specified as:

1. "Left mid prostate margin" is a small tan-pink fragment 0.2 cm in greatest dimension. The specimen was placed into a green cassette labeled with the patient's name and 1FS. Received in _____ is a formalin-filled container with a specimen matching the above description. The entire contents of the green cassette are transferred to an orange cassette labeled with patient's name and 1FS.
2. "Fat + lymph nodes anterior to prostate" is a yellow adipose specimen measuring 3.2 x 3.4 x 1.7 cm. The specimen is examined for candidate lymph nodes and 2 possible candidate lymph nodes were detected measuring 0.5 and 0.2 cm. The candidate lymph nodes are placed into a white cassette labeled _____, while a candidate blood vessel is placed into a white cassette labeled _____ and the remaining fibroadipose tissue is placed into a white cassette labeled _____.
3. "R obturator L.N." are 2 fibrofatty tissue specimens 5.5 x 3.6 x 1.8 cm, and 1.8 x 1.1 x 0.3 cm. The specimens are examined for candidate lymph nodes and 4 candidate lymph nodes are found ranging in size from 0.2 cm to 4.4 cm. The smaller lymph nodes are placed into a white cassette labeled _____ the largest lymph node is bivalved and bisected and placed into 4 white cassettes labeled _____. The remaining fibroadipose tissue is placed into a white cassette labeled _____.
4. "Left obturator L.N." are 2 fibrofatty tissue specimens measuring 4.6 x 2.4 x 1.8 cm and 4.4 x 3.8 x 1.8 cm. The specimens are examined for candidate lymph nodes and 3 candidate lymph nodes are found ranging in size from 0.6 to 3.1 cm. The 3 candidate lymph nodes are placed into white cassettes labeled _____ while the remaining fibroadipose tissue is placed into a white cassette labeled _____.
5. "Right external iliac L.N." is a yellow fibroadipose tissue specimen measuring 4.2 x 4.6 x 1.7 cm. The specimen is examined for candidate lymph nodes and 2 candidate lymph nodes are found ranging in size from 0.6 to 3.3 cm. The smallest lymph node is placed into a white cassette labeled _____ while the larger lymph node is bisected and placed into white cassettes labeled _____ 5C, while the remaining fibroadipose tissue is entirely placed into a white cassette labeled _____.
6. "Left external iliac L.N." is a yellow fibrofatty tissue specimen

[page 4 of 5]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology	Final Results
---------------------------	----------------------

measuring 3.8 x 3.8 x 2.3 cm. The specimen is examined for candidate lymph nodes and 5 candidate lymph nodes are found measuring 0.9 to 4.6 cm. The smaller lymph nodes are placed into a white cassette labeled _____ and 6B, while the largest lymph node is bisected and placed into white cassettes labeled _____ and 6D. The remaining fibroadipose tissue is entirely placed into a white cassette labeled _____

7. "Right common iliac L.N." is an irregular tan-brown fibroadipose tissue measuring 1.7 x 2.3 x 1.1 cm. The specimen is examined for candidate lymph nodes and 1 candidate lymph node is detected measuring 1.5 cm. The lymph node is entirely placed into a white cassette labeled _____, while the remaining fibroadipose tissue is placed into a white cassette labeled _____

8. "Left common iliac L.N." is an irregular yellow fibroadipose tissue specimen measuring 1.2 x 1.2 x 0.6 cm. The specimen is examined for candidate lymph nodes and none are found. The entire specimen is placed into a white cassette labeled _____

9. "Right internal iliac L.N." is an irregular rubbery fatty yellow tissue specimen measuring 1.8 x 1.7 x 1.4 cm. The specimen is examined for candidate lymph nodes and 2 candidate lymph nodes are found measuring 1.0 and 0.3 cm. The lymph nodes and remaining fibroadipose tissue are entirely placed into a white cassette labeled _____

10. "Left internal iliac nodes" are 2 irregular yellow fatty tissue specimens measuring 1.8 x 1.8 x 1.1 cm and 0.6 x 0.7 x 0.5 cm. The specimens are examined for candidate lymph nodes and 1 is found measuring 0.6 cm. The lymph node is placed into a white cassette labeled _____. A while the remaining fibroadipose tissue is placed into a white cassette labeled _____

11. "Prostate" consists of a prostatectomy specimen weighing 61.30 grams with the following measurements:

Left to right: 5.0 cm

Anterior to posterior: 4.3 cm

Apex to base: 4.2 cm

Left seminal vesicle: 4 x 2.1 x 0.8 cm

Left vas deferens: 5.1 cm in length x 0.5 cm in diameter

Right seminal vesicle: 3.2 x 1.7 x 0.8 cm

Right vas deferens: 6.7 cm in length x 0.5 cm in diameter

There are sutures along the left side of the prostate. The prostate is inked as follows: Urethra in yellow, anterior one-third in black, right posterior two-thirds in blue, and left posterior two-thirds in red. Gross photographs are taken. One cut is made revealing a tan nodular cut surface and a yellow nodular area measuring 2.1 x 1.5 x 1.5 cm in the left posterior peripheral aspect of the prostate. Approximately 0.8 x 0.8 x 0.3 cm of tumor from the left posterior periphery, approximately 0.8 x 0.6 x 0.3 cm of tumor from the left posterior periphery, and approximately 1.5 x 1.5 x 0.2 cm of normal-appearing prostatic

[page 5 of 5]
Gender: Male	Birth Date	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology

Final Results

tissue from the right posterior are procured for the by
The procurement was documented/performed by
and at Received in
is the above specimen. The seminal vesicles and vas
deferens are dissected off the main prostate specimen. A whole
mount generated through prior imaging is brought to the
The prostate is placed in the whole mount. Serial
sections are made and placed into white biopsy bags labeled
11G. A sliver of the posterior prostate is placed
into a white cassette labeled H. Right and left
seminal vesicles and vas deferens are placed into white cassettes
labeled The left vas deferens is serially
sectioned and placed entirely into white cassettes labeled
The right seminal vesicle and vas deferens are
serially sectioned and placed entirely into

All cassettes are submitted for permanent processing.

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Source: NCI Genomic Data Commons file 43d5039e-dafb-47ef-ba9c-97f362b10a73 (TCGA-VN-A88R.6DDC4292-91C9-49A7-B34D-578ECA0A7F56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).